Gene-level copy-number profile of tumor specimen TCGA-FV-A496-01A from TCGA case TCGA-FV-A496, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 84.7 years (30,950 days).
Specimen TCGA-FV-A496-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.20af3488-d9c8-439b-8361-e89249f37677.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FV-A496-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/aa410aca-aad5-4970-a9ee-daa6a7d41342

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,199; copy number 2: 9,606; copy number 3: 12,903; copy number 4: 28,693; copy number 5: 4,031; copy number 6: 2,792; copy number 7: 548; copy number 8: 37; copy number 9: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FV-A496-01A-11D-A25U-01): tumor purity 0.86, ploidy 3.62, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:154,697,455–154,974,395, 8 genes, copy number 9 (within-gene range 6–9): KCNN3, PMVK, AL451085.1, PBXIP1, Metazoa_SRP, PYGO2, AL451085.2, SHC1.

Autosomal genes at a single copy (total copy number 1): 681. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
